Gene-level copy-number profile of tumor specimen TCGA-B2-5635-01B from TCGA case TCGA-B2-5635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.4 years (27,183 days).
Specimen TCGA-B2-5635-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.99275492-91fa-4f9e-9bba-70cb57fff80e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B2-5635-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/40526b35-0013-40d2-a2e5-54afe7abb223

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,394; copy number 2: 57,723; copy number 3: 37; copy number 4: 75; copy number 5: 8; copy number 6: 14; copy number 7: 18.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B2-5635-01A-01D-A274-01): tumor purity 0.53, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:101,457,241–101,458,626, 2 genes: AC110994.2, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,081,831–130,113,227, 1 gene, copy number 5 (within-gene range 2–5): ALG1L2.
- chr3:130,099,092–130,201,336, 5 genes, copy number 5: FAM86HP, LINC02021, ENPP7P3, AC130888.1, SNRPCP8.
- chr10:93,893,973–93,956,062, 1 gene, copy number 6 (within-gene range 2–6): SLC35G1.
- chr14:38,973,399–38,987,383, 2 genes, copy number 5: AL132994.2, Y_RNA.
- chr14:70,906,657–70,907,111, 1 gene, copy number 7: AC004825.2.
- chr15:25,054,210–25,079,149, 12 genes, copy number 7: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13.
- chr15:25,228,967–25,250,940, 13 genes, copy number 6: SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:3,100,696–3,149,963, 5 genes, copy number 7 (within-gene range 2–7): ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P.

Autosomal genes at a single copy (total copy number 1): 23. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
